Gene-level copy-number profile of tumor specimen TCGA-DU-6396-01A from TCGA case TCGA-DU-6396, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.3 years (11,427 days).
Specimen TCGA-DU-6396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.618cc414-7e4d-4840-8a68-191713302540.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6396-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ff25818-f39d-42bf-824c-3d49b1dbaf43

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 978; copy number 2: 3,728; copy number 3: 7,056; copy number 4: 45,730; copy number 5: 232; copy number 6: 2,073; copy number 9: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6396-01A-11D-1704-01): tumor purity 0.63, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:119,608,423–120,333,686, 18 genes, copy number 9 (within-gene range 4–9): AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1, AP003390.1, AP001994.1, AP001994.2, AP001994.3, AP001360.3, LINC02744, AP001360.1, AP001360.2, TRIM29, AP000679.1, OAF, POU2F3, AP001150.1, TLCD5.

Autosomal genes at a single copy (total copy number 1): 346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
